Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GY, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GY-01A (Primary Tumor).

[page 1 of 3]
GROSS:

Specimen status: Received in formalin

Operation: Distal gastrectomy

Organ:

Stomach (great curvature: 18.5 cm, lesser curvature: 17.0 cm,
proximal resection margin: 15.0 cm, distal resection margin: 5.0 cm)

Duodenum (3.0 cm in length)

Lesion

A well defined ulcerofungation mass (3.0 x 2.5 x 0.5 cm) in antrum

Location: Lower 1/3 (antrum), lesser curvature

From proximal resection margin - 9.5 cm

From distal resection margin - 5.0 cm

Gross serosal invasion: Absent

Blocks

TB, T1-5, tumor and surrounding tissue x 6

NB, A, antral mucosa x 2

B, body mucosa x 1

P, proximal resection margin x 1

DRM, D, distal resection margin x 2

LN1-2, superior gastric lymph nodes x 2

LN3-5, inferior gastric lymph nodes x 3

LN6, '1' lymph node x 1

LN7, '4sb' lymph node x 1

LN8, '5' lymph node x 1

LN9-10, '6' lymph node x 2

LN11, '7' lymph node x 1

LN12, '8' lymph node x 1

LN13, '9' lymph node x 1

LN14-15, '11p' lymph node x 2

LN16, '12' lymph node x 1

1CD-0-3

adenocarcinoma, diffuse type 8145/3

Site: Stomach, antrum c16.3

hw 9/27/12

MICROSCOPIC

<WHO histologic typing>

Adenocarcinoma, tubular, poorly differentiated

Depth of invasion:

T4: T4a-Tumor penetration of serosa (SE)

Margins:

[page 2 of 3]
Proximal resection margin: Uninvolved
Distal resection margin: Uninvolved
Lauren classification: Diffuse
Ming (Growth pattern) classification: Infiltrative
Lymphoid reaction: Absent
Lymphovascular invasion: Present
Venous (large vessel) invasion: Absent
Perinerve invasion: Present
Polyps: No
Lymph node metastasis: Present
Distant metastasis: Cannot be assessed
Pathologic stage: pT4N1MX (AJCC 7th edition)

DIAGNOSIS:

Stomach, distal gastrectomy:
Adenocarcinoma, poorly differentiated, infiltrating
(Advanced cancer)

<Addendum>

Final diagnosis: Stomach Adenocarcinoma, Diffuse Type *per clarification by TSS.*

Dx discrepancy from attached

Lymph node, perigastric, distal gastrectomy:
Superior gastric: No tumor present (0/8)
Inferior gastric: No tumor present (0/15)

lw
10/9/12

Lymph node, regional, excision:
Labeled '1': No tumor present (0/1)
Labeled '4sb': No tumor present (0/2)
Labeled '5': No tumor present (0/1)
Labeled '6': Metastatic carcinoma, primary in stomach (1/10)
Labeled '7': No tumor present (0/7)
Labeled '8': No tumor present (0/1)
Labeled '9': No tumor present (0/4)
Labeled '11': No tumor present (0/12)
Labeled '12': No tumor present (0/1)

Diagnostic Discrepancy		☒
Reviewed Initials	lml	9/11/12

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcino

Completed By |

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Tubular Adenocarcinoma, Diffuse	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Adenocarcinoma, Diffuse Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	According to the original pathology report, this tumor is described as a poorly-differentiated tubular adenocarcinoma. In addendum, we clarified the final diagnosis as an stomach adenocarcinoma, diffuse type	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file f570217e-5631-4e08-8e7c-55716c39cd67 (TCGA-HU-A4GY.4A66179A-550C-4839-9075-7E7639D7CEC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).